Somatic mutation profile of tumor specimen TCGA-V1-A8X3-01A (aliquot TCGA-V1-A8X3-01A-11D-A377-08) from TCGA case TCGA-V1-A8X3, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8X3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 628a8cf3-78a0-42aa-a9e2-6fe43dcbb8cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A8X3-10A (Blood Derived Normal), aliquot TCGA-V1-A8X3-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c18a3014-8b88-43b0-9d3f-29bdb6757d8a

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, Nonsense Mutation 4, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVRL1 | c.19A>G p.R7G | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV101187798; called by muse, mutect2, varscan2
- ASH1L | c.3232C>T p.Q1078* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as COSV100853193; called by muse, mutect2, varscan2
- BPIFB4 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 25/83 reads (30%) | catalogued as rs377208700, COSV100971443; called by muse, mutect2, varscan2
- CDH23 | c.569T>A p.I190N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.272); catalogued as COSV99819333; called by muse, mutect2
- CNTNAP5 | c.1282G>A p.V428M | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.167); catalogued as rs368773037; called by muse, mutect2, varscan2
- FBXO38 | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV99693177; called by muse, mutect2, varscan2
- FEM1A | c.1685A>G p.H562R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99521386; called by muse, mutect2, varscan2
- HTT | c.5671A>G p.R1891G | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as rs1560592114, COSV100750518; called by muse, mutect2, varscan2
- MAOA | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100108649; called by muse, mutect2, varscan2
- MAP3K4 | c.4193A>G p.K1398R | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.585); catalogued as COSV62332751; called by muse, mutect2
- MUC5AC | c.15655G>A p.D5219N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.489); catalogued as rs778345946, COSV100611345; called by muse, mutect2, varscan2
- MXRA5 | c.3067A>G p.I1023V | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs373344927, COSV99476049; called by muse, mutect2, varscan2
- NOX3 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.427); catalogued as rs748834229, COSV50148519; called by muse, mutect2
- PYCR1 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.514); catalogued as rs139869668; called by muse, mutect2, varscan2
- RBP3 | c.2849A>G p.D950G | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs1555211563; called by muse, mutect2, varscan2
- SAMD9L | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as rs369074740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SI | c.4510C>T p.R1504* | Nonsense Mutation (SNP) | VAF 23/114 reads (20%) | catalogued as rs1164456060, COSV52265207; called by muse, mutect2, varscan2
- STK39 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV100596304; called by muse, mutect2, varscan2
- ZNF41 | c.392G>A p.C131Y | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- ADCY4 | c.2454C>T p.F818= | Silent (SNP) | VAF 6/130 reads (5%) | catalogued as COSV100156235; called by muse, mutect2
- CUL4A | c.1851G>A p.T617= (on ENST00000375440 / NM_001008895.4; = p.T517= on NM_003589.3) | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs200453565; called by muse, mutect2, varscan2
- FRMPD4 | c.3592C>A p.R1198= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV101042325; called by muse, mutect2
- GPR3 | c.342C>T p.G114= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as rs776184813, COSV100927498; called by muse, mutect2, varscan2
- RYR3 | c.14607A>C p.G4869= (on ENST00000389232; = p.G4870= on NM_001036.6) | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100145334; called by muse, mutect2
- SCN8A | c.3126C>A p.A1042= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as rs1320040197; called by muse, mutect2
- UAP1L1 | c.1299G>A p.R433= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1459148648, COSV100814414; called by muse, mutect2, varscan2
- UNC5D | c.240C>T p.A80= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV99772885; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498879 C>T | 5'Flank (SNP) | VAF 7/63 reads (11%) | catalogued as rs780315745; called by muse, mutect2, varscan2
- PDE7A | c.139-6091T>G | Intron (SNP) | VAF 45/146 reads (31%) | catalogued as COSV101052616; called by muse, mutect2, varscan2
